Surgical pathology report (de-identified scan), CDDP_EAGLE case CDDP-ABIX, project CDDP_EAGLE-1 (CDDP Integrative Analysis of Lung Adenocarcinoma (Phase 2)), specimen CDDP-ABIX-TTP2-A (Primary Tumor).

SPECIMEN(S) RECEIVED:

- A) Right lung and pericardium
- B) Paratracheal lymph nodes
- C) Subcarinal lymph nodes, biopsy

GROSS EXAMINATION:

A) Lung measuring 12x18x6 cm with perihilar nodular neoplasm of the lower lobe, measuring 5 cm in greatest diameter, whitish in color, with scalloped margins, located 6 cm from the margin of surgical resection. Yellowish-white edge of tissue also present, representing the parietal pericardium. Eight peribronchial lymph nodes were isolated. Remainder of parenchyma appears congested.

A1-A3 neoplasm

A4 bronchial margin

A5-A6/A9-A10 lymph nodes

A7 distant parenchyma of lower lobe and parenchyma of middle lobe

A8 parenchyma of upper lobe

B) Six lymph nodes measuring between 0.5 and 1.2 cm in greatest diameter.

C) Two fragments measuring 0.6 and 1 cm in greatest diameter.

CDDP-YP-ABIX-01-PR

DIAGNOSIS:

A) Poorly differentiated adenocarcinoma with papillary, bronchioalveolar, and pleomorphic features, partially necrotic, in the lower lobe of the lung, focally extensive and infiltrating into the contiguous parietal pericardium. Presence of peritumoral and distant neoplastic vascular invasion.

Neoplasia is present in the area of peribronchial tissue from the bronchial margin of surgical resection.

Lymph node and perinodal metastases of adenocarcinoma in 8/8 lymph nodes.

Fatty inflammation of the lung and vascular congestion of the peritumoral lung parenchyma; emphysema and paraseptal fibrosis in the remainder of the pulmonary parenchyma.

B) Lymph node and perinodal metastases of carcinoma in 6/6 lymph nodes.

C) Lymph node and perinodal metastases of carcinoma in 2/2 lymph nodes.

Histopathologic staging:

pT3; N2

1CD-0-3

adenocarcinoma with mixed subtypes 8255/3

cocf (Per TSS) Site: @ lung, upper lobe C34.1

Path — Site: @ lung, lower lobe C34.3

1CD-0-3

C34.11

hw 2/12/16

Source: NCI Genomic Data Commons file fe5a570d-4873-4263-bef2-d3a8ff51ce35 (CDDP-ABIX-TTP2.B9E25549-444C-46DA-A236-C0C3920F7022.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).